Somatic mutation profile of tumor specimen MP2PRT-PAPVDY-TMP1-A (aliquot MP2PRT-PAPVDY-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPVDY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.0 years (371 days).
Specimen MP2PRT-PAPVDY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ef0db8c-2aa0-4c50-8754-dd2060e8c5c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPVDY-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPVDY-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cddf9bc-71ea-43b6-bb8f-2105627452ee

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 17/240 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 22/229 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CACNA1G | c.4441G>A p.V1481I | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772369809, COSV100662427; called by muse, mutect2, varscan2
- COQ4 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as rs750609726; called by muse, mutect2
- PLS3 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 25/307 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- TJP1 | c.4005G>A p.K1335= | Silent (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
